Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5183, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5183-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with enhancing left renal mass.

TCGA-BP-5183

Specimens Submitted:

1: SP: Kidney, left, partial nephrectomy

2: SP: Kidney, left, biopsy

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.2 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Compression-related changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Kidney, left, biopsy

Benign renal medullary tissue.

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Gross Description:

1).The specimen is received fresh for frozen section diagnosis and is labeled "left renal tumor for diagnosis stitch marks deep margin". It consists of a 7.5 x 5.5 x 5.2 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 5.2 x 4.8 x 4.4 cm well-circumscribed yellow focally hemorrhagic and cystic mass. The clearance from the resection margin is 0.3 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. A photograph is taken. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - Uninvolved kidney parenchyma

2).The specimen is received fresh for frozen section diagnosis, labeled "Question satellite tumor left kidney and question papilla " and consists of a 0.4 x 0.3 x 0.2 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:

FSC -frozen section control

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
1	RS	1
4	T	4

Part 2: SP: Kidney, left, biopsy

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. DEFER TO PERMANENT MARGINS ARE FREE OF TUMOR ON REPRESENTATIVE SECTION (4 MM CLEARANCE).
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN MEDULLARY RENAL TISSUE
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file d1f44fc9-91aa-478e-8c71-96dbd3af68bd (TCGA-BP-5183.A15A0DFF-41AC-4D3B-B16F-B1A98198A203.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).